Gene-level copy-number profile of tumor specimen TCGA-D5-6922-01A from TCGA case TCGA-D5-6922, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.0 years (27,771 days).
Specimen TCGA-D5-6922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c8c14982-3cf4-4b0f-83aa-649752e56a37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6922-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63d2eddb-4107-43e7-94e6-555de3e41b35

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,567; copy number 2: 10,777; copy number 3: 31,327; copy number 4: 11,587; copy number 5: 1,416; copy number 6: 2,950; copy number 7: 195.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6922-01A-11D-1923-01): tumor purity 0.6, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 195 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:29,476,515–29,595,688, 2 genes, copy number 7: MTUS2-AS1, SLC7A1.
- chr18:42,159,283–42,691,422, 1 gene, copy number 7 (within-gene range 1–7): LINC00907.
- chr18:42,649,520–44,071,701, 7 genes, copy number 7: AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455.
- chr20:20,017,310–30,312,480, 185 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,567. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
